Somatic mutation profile of tumor specimen HCM-BROD-0028-C71-01A (aliquot HCM-BROD-0028-C71-01A-01D-A77E-36) from HCMI case HCM-BROD-0028-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.9 years (21,523 days).
Specimen HCM-BROD-0028-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b84cbcaf-300c-453b-80a3-32dbbb23ac35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0028-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0028-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0487d1a7-d355-4af0-9829-fb30f689f8fb

The open-access MAF lists 110 somatic variants for this specimen: 77 protein-altering or splice-affecting, 16 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Frame Shift Del 8, Intron 7, Nonsense Mutation 6, 5'UTR 3, 5'Flank 3, Splice Region 2, RNA 2, 3'UTR 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 47/266 reads (18%) | catalogued as rs121908749, CM126469, CM940236, COSV99141556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 116/488 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs397514560, CM1212354, COSV64293891, COSV64295025, COSV64300549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SZT2 | c.4396C>T p.R1466* (on ENST00000634258 / NM_001365999.1; = p.R1409* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 88/213 reads (41%) | catalogued as rs766090540, COSV100987791; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGK | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.075); catalogued as rs180770509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62341659; called by muse, mutect2, varscan2
- ALPK2 | c.273C>G p.N91K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749338615; called by muse, varscan2
- DBH | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as rs963604579; called by muse, mutect2, varscan2
- DHX34 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553380305, COSV60898753; called by muse, mutect2, varscan2
- FAM83C | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs148042046; called by muse, mutect2, varscan2
- FMN1 | c.3639G>T p.K1213N (on ENST00000616417 / NM_001277313.2; = p.K990N on NM_001103184.4) | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57930588; called by muse, mutect2, varscan2
- FN1 | c.725T>G p.I242S | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60556538; called by muse, mutect2, varscan2
- GCNT1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs368265529, COSV65058001; called by muse, mutect2, varscan2
- HAUS8 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs779654027; called by muse, mutect2, varscan2
- HS3ST6 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530650215, COSV99562847; called by muse, mutect2
- KAT7 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52013419; called by muse, mutect2, varscan2
- KCNC2 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs572944602; called by muse, mutect2, varscan2
- MYLK | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 141/485 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs770980369, COSV100658752; called by muse, mutect2, varscan2
- NELFB | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs752724218; called by muse, mutect2, varscan2
- NFE2L3 | c.778_779del p.F260Lfs*14 | Frame Shift Del (DEL) | VAF 29/182 reads (16%) | catalogued as rs866076365; called by mutect2, pindel, varscan2
- NOL8 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1433207665, COSV62634212, COSV62637446; called by muse, mutect2
- NOL8 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs200196088, COSV100694521; called by muse, mutect2
- PHTF2 | c.1043G>A p.R348H (on ENST00000248550 / NM_001366089.1; = p.R310H on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs370027222; called by muse, mutect2, varscan2
- PREX2 | c.4250G>T p.G1417V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV55793305; called by muse, mutect2, varscan2
- RAB33A | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as rs146928242; called by muse, mutect2, varscan2
- RYR1 | c.7208G>A p.R2403H | Missense Mutation (SNP) | VAF 111/565 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs749136416, COSV62087171; called by muse, mutect2, varscan2
- SLC9A3 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406350252; called by muse, mutect2, varscan2
- TAT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 143/534 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs150886066; called by muse, mutect2, varscan2
- TET3 | c.5230C>T p.R1744C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs747079275; called by muse, mutect2, varscan2
- TGFA | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782577747, COSV54912877; called by muse, mutect2, varscan2
- TGFBI | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV59354613; called by muse, mutect2, varscan2
- TRIM40 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 122/525 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV57156653, COSV57156976; called by muse, mutect2, varscan2
- TRIP11 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs149954353; called by muse, mutect2, varscan2
- TRPC7 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 42/191 reads (22%) | catalogued as rs1432751859, COSV100725651; called by muse, mutect2, varscan2
- UBQLN2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.034); catalogued as COSV57739935; called by muse, mutect2, varscan2
- ZCCHC12 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1274558588, COSV100038612; called by muse, mutect2, varscan2
- ZCCHC2 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99502699; called by muse, mutect2, varscan2
- ZNF202 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as rs1321667568, COSV100279136; called by muse, mutect2, varscan2
- ZNF493 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV62749022; called by muse, mutect2, varscan2
- ABL1 | c.2611_2617del p.E871Pfs*3 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- ALS2 | c.1870T>C p.F624L | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- B4GALT4 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- BCR | c.3071G>A p.G1024E | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- BRSK1 | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 92/309 reads (30%) | called by muse, mutect2, varscan2
- COL4A6 | c.279T>A p.D93E | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DIRAS3 | c.479A>T p.E160V | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK4 | c.3316-3C>T | Splice Region (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- DYM | c.301del p.W101Gfs*14 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | called by mutect2, pindel, varscan2
- EIF3H | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FLCN | c.856A>C p.M286L | Missense Mutation (SNP) | VAF 160/575 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMO5 | c.902A>C p.K301T | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRRS1 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIPAP1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 76/253 reads (30%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERC1 | c.8112A>G p.I2704M | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LAMA5 | c.2064_2067del p.C689Tfs*13 | Frame Shift Del (DEL) | VAF 34/156 reads (22%) | called by mutect2, pindel, varscan2
- LCE3E | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 140/522 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCTP2 | c.554_561dup p.L188* | Frame Shift Ins (INS) | VAF 46/206 reads (22%) | called by mutect2, varscan2
- MEIOC | c.622T>G p.Y208D | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MYO15A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 62/272 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- PHF11 | c.324+2T>C p.X108_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- PLCXD2 | c.765_769del p.S256Gfs*32 | Frame Shift Del (DEL) | VAF 85/406 reads (21%) | called by mutect2, pindel, varscan2
- PLXNC1 | c.114del p.V39Cfs*104 | Frame Shift Del (DEL) | VAF 112/494 reads (23%) | called by mutect2, pindel, varscan2
- PLXND1 | c.4133T>G p.L1378R | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- RNASE2 | c.151_152del p.T51Qfs*7 | Frame Shift Del (DEL) | VAF 57/303 reads (19%) | called by mutect2, pindel, varscan2
- RO60 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR1 | c.11360-2del p.X3787_splice | Splice Site (DEL) | VAF 78/475 reads (16%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SLCO5A1 | c.1226T>A p.V409D | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMTN | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOCS7 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SPON2 | c.734_741del p.R245Pfs*17 | Frame Shift Del (DEL) | VAF 32/186 reads (17%) | called by mutect2, pindel, varscan2
- SULT1B1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- TCEA2 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TECPR2 | c.3318C>T p.G1106= | Splice Region (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- TP53I13 | c.12_14del p.P6del | In Frame Del (DEL) | VAF 75/318 reads (24%) | called by pindel, varscan2
- ZNF737 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ALK | c.672T>C p.H224= | Silent (SNP) | VAF 72/298 reads (24%) | called by muse, mutect2, varscan2
- C1QL2 | c.111T>A p.T37= | Silent (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- DISP2 | c.4137T>C p.N1379= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs771631656; called by muse, mutect2, varscan2
- DRD5 | c.555G>A p.A185= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs1461653045, COSV100431960; called by muse, mutect2, varscan2
- ERO1A | c.696T>G p.T232= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- GTF3C3 | c.165A>G p.S55= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as rs375698779; called by muse, mutect2, varscan2
- LCA5 | c.729G>A p.S243= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs756379569, COSV63970954; called by muse, mutect2
- MMRN1 | c.3159G>C p.G1053= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99307921; called by muse, varscan2
- OR6P1 | c.690G>A p.T230= | Silent (SNP) | VAF 167/608 reads (27%) | catalogued as rs531306117, COSV58109054; called by muse, mutect2, varscan2
- OR8H2 | c.477C>T p.N159= | Silent (SNP) | VAF 48/185 reads (26%) | catalogued as rs554066587, COSV100542521; called by muse, mutect2, varscan2
- RGL1 | c.480A>G p.R160= (on ENST00000360851 / NM_001297672.2; = p.R195= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 85/298 reads (29%) | called by muse, mutect2, varscan2
- RTN1 | c.1866C>T p.S622= | Silent (SNP) | VAF 171/549 reads (31%) | catalogued as rs772270786, COSV50721100; called by muse, mutect2, varscan2
- SLC6A14 | c.139C>T p.L47= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as COSV100903220; called by muse, mutect2, varscan2
- TENM2 | c.477C>T p.N159= | Silent (SNP) | VAF 110/400 reads (28%) | catalogued as rs763730897, COSV72862642; called by muse, mutect2, varscan2
- TGIF2LX | c.330G>A p.P110= | Silent (SNP) | VAF 151/629 reads (24%) | catalogued as rs1293739273, COSV99383324; called by muse, mutect2, varscan2
- TJP3 | c.1137C>T p.P379= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs769361845, COSV53662741; called by muse, mutect2, varscan2
- ARFRP1 | c.417+542_417+543insA | Intron (INS) | VAF 66/248 reads (27%) | catalogued as rs386394225; called by mutect2, varscan2
- ARMCX4 | c.1038+1562G>C | Intron (SNP) | VAF 93/326 reads (29%) | called by muse, mutect2, varscan2
- FCF1 | c.*26_*30del | 3'UTR (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel
- GLT1D1 | c.68+10522C>T | Intron (SNP) | VAF 9/36 reads (25%) | catalogued as rs954687956; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457629 A>G | 5'Flank (SNP) | VAF 31/336 reads (9%) | catalogued as rs1312171368; called by muse, mutect2, varscan2
- LIMA1 | c.1141-3359T>A | Intron (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- LINC02740 | n.286G>A | RNA (SNP) | VAF 56/245 reads (23%) | catalogued as rs965426550; called by muse, mutect2, varscan2
- MARK3 | c.1872-39T>G | Intron (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- NDUFV2 | c.-2C>T | 5'UTR (SNP) | VAF 96/340 reads (28%) | catalogued as rs528658653, COSV100571724; called by muse, mutect2, varscan2
- OR7D1P | n.525G>A | RNA (SNP) | VAF 56/340 reads (16%) | catalogued as rs539111941; called by muse, mutect2, varscan2
- PTGFRN | c.-135C>T | 5'UTR (SNP) | VAF 118/333 reads (35%) | catalogued as rs904326120; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790930 C>T | 5'Flank (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2
- RNU6-467P | chr17:20321375 T>C | 5'Flank (SNP) | VAF 52/196 reads (27%) | called by muse, mutect2, varscan2
- RTN3 | c.*151C>T | 3'UTR (SNP) | VAF 12/39 reads (31%) | catalogued as rs761755900; called by muse, mutect2, varscan2
- SPACA7 | c.-1C>T | 5'UTR (SNP) | VAF 59/165 reads (36%) | called by muse, mutect2, varscan2
- TFR2 | c.615-28C>T | Intron (SNP) | VAF 63/279 reads (23%) | catalogued as rs745475672; called by muse, mutect2, varscan2
- VARS1 | c.2418+13_2418+17delinsCC | Intron (DEL) | VAF 51/223 reads (23%) | called by pindel, varscan2*
